TCGA case TCGA-BR-A44T — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/98bf4652-0088-4ecc-9dfa-376438cb063c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Carcinoma, diffuse type (the primary disease): ICD-O-3 morphology code: 8145/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 53.1 years (19,407 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 10.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 47 days; Days to treatment end: 196 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 47 days; Days to treatment end: 196 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Fluorouracil; Days to treatment start: 682 days (1.9 years); Days to treatment end: 714 days (2.0 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 682 days (1.9 years); Days to treatment end: 714 days (2.0 years); Treatment outcome: Stable Disease.
2. Recurrence of diagnosis 1 (Carcinoma, diffuse type). Age at diagnosis: 55.0 years (20,089 days); Days to diagnosis: 682 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.

Follow-up (5 entries)
- Days to follow up: 13 days; Disease response: Tumor Free.
- Days to follow up: 382 days (1.0 years); Disease response: Tumor Free.
- Day 682 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 682 days (1.9 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 762 days (2.1 years); Disease response: With Tumor.
- Days to follow up: 1,038 days (2.8 years); Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-A44T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,140 mg.
  Slide TCGA-BR-A44T-01A-03-TSC: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 65; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
  Slide TCGA-BR-A44T-01A-01-TSA: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 25; Percent normal cells: 2; Percent necrosis: 0; Percent stromal cells: 73; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-BR-A44T-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-A44T-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Diffuse Type; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Cardia/Proximal; Lymph nodes examined: Yes; Cancer procurement city: Kiev; History reflux disease indicator: No; History barretts esophageal indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 2, New neoplasm event types: New tumor event type: Locoregional Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,038 days; disease-specific survival: no event (censored), 1,038 days; disease-free interval: event (new tumor event after initially disease-free), 682 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 682 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-A44T-01A-32D-A24C-01): tumor purity 0.64, ploidy 2.01, whole-genome doublings 0.
